Gene-level copy-number profile of tumor specimen C3L-01032-01 from CPTAC case C3L-01032, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.8 years (19,276 days).
Specimen C3L-01032-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4e38c01-7a1b-4d1f-bfb3-929729688636.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01032-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/cd414463-5ac2-4518-b296-4b3afb75ef17

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 152; copy number 1: 5,859; copy number 2: 45,300; copy number 3: 6,370; copy number 4: 37; copy number 5: 685.

Homozygous deletions (total copy number 0; autosomes only): 152 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr9:20,502,265–24,592,104, 76 genes (within-gene range 0–1) (broad region; genes not listed).
- chr12:125,958,688–128,027,166, 49 genes: LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.1, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC087894.3, AC087894.2, AC087894.1, LINC02393, LINC00507, LINC00508, LINC02441.
- chr17:18,450,244–18,551,705, 9 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:50,968,019–53,535,903, 16 genes (within-gene range 0–2): AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 685 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:98,943,595–134,713,049, 476 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:138,588,235–145,066,685, 209 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,859. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
